CCDI case PBCTDI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/1ea607ce-298d-4351-afe0-9069f0daa021

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 0.7 years (254 days).

Biospecimens (3 samples)
- Sample 0DYUZ4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYV13: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DYV1H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
